Surgical pathology report (de-identified scan), TCGA case TCGA-12-3648, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Duke, specimen TCGA-12-3648-01A (Primary Tumor).

[page 1 of 2]
Patient: [REDACTED]

CGA-12-3648

AP Surgical Pathology: Additional Info [REDACTED] Acc# [REDACTED]

Surg Path

CLINICAL HISTORY:

[REDACTED] female with right temporal brain tumor.

[REDACTED] In the right temporal lobe there is a large rim enhancing lesion measuring 4.7 x 3.7 cm without significant mass effect or definite vasogenic edema. Large central component without enhancement with decreased T1 signal intensity. Several smaller enhancing lesions are identified posterior to the dominant lesion, largest measuring approximately 1.5 cm. No other areas of abnormal signal intensity or enhancement are identified throughout the brain parenchyma.

GROSS EXAMINATION:

A. "Brain tissue (AF1)". Received fresh for frozen section is a 36 gm (5.5 x 5.5 x 2.4 cm) portion of brain with diffuse surface hemorrhage and no well demarcated white and gray matter. A portion of the specimen was frozen as representative AF1 and the frozen section remnant is submitted in block A1 and additional representative sections are submitted in blocks A2-A5 and the remainder is retained in formalin.

INTRA OPERATIVE CONSULTATION:

A. "Brain tissue": AF1- high-grade glioma [REDACTED].

MICROSCOPIC EXAMINATION:

The tissue is a large resection specimen of brain that exhibits a small cell anaplastic proliferation of astrocytic cells associated with vascular proliferation and pseudopalisading necrosis.

DIAGNOSIS:

A. "BRAIN TISSUE" (CRANIOTOMY):

GLIOBLASTOMA (WHO GRADE IV).

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]
Electronically signed: [REDACTED]

ADDENDUM 1:

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

FISH INTERPRETATION SUMMARY:

CHROMOSOME 7 CENTROMERE - POLYSOMY (82% OF TUMOR CELLS EXHIBIT POLYSOMY)

EGFR - AMPLIFICATION (93% OF TUMOR CELLS EXHIBIT AMPLIFICATION)

CHROMOSOME 10 CENTROMERE - CENTROMERE LOSS (59% OF TUMOR CELLS EXHIBIT LOSS)

PTEN - ALLELIC LOSS (72% OF TUMOR CELLS EXHIBIT LOSS)

9p21 - LOSS (52% OF TUMOR CELLS EXHIBIT LOSS)

[page 2 of 2]
CHROMOSOME 9 CENTROMERE - CENTROMERE LOSS (41% OF TUMOR CELLS EXHIBIT LOSS)

4 OF 4 ABNORMAL MARKERS AND 9P21 EXHIBITS LOSS.

COMMENT: A MULTIVARIATE SURVIVAL ANALYSIS OF [REDACTED] PATIENTS WITH GLIOBLASTOMAS REVEALS THAT THE HAZARD OF SHORT SURVIVAL AMONG PATIENTS WITH 0-2 ABNORMAL MARKERS (OUT OF 4) WAS SIGNIFICANTLY LOWER THAN THAT FOUND WITH PATIENTS WITH 4 ABNORMAL MARKERS EVEN AFTER ADJUSTMENT FOR AGE EFFECT.

BOTH FISH AND IMMUNOHISTOCHEMISTRY FOR PTEN REVEAL SIMILAR FINDINGS INDICATIVE OF LOSS OF PTEN STATUS.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]
Electronically signed: [REDACTED]

ADDENDUM 2:

IMMUNOHISTOCHEMICAL LABELING INDEX OF TUMOR CELLS:

TISSUE TYPE: BRAIN TISSUE CONTAINING GLIOBLASTOMA (WHO GRADE IV; [REDACTED])

LEUCOCYTE COMMON ANTIGEN (LCA): 15% OF POSITIVE CELLS.

PROLIFERATION INDEX INTERPRETATION: HIGH PROLIFERATION INDEX (20% OF TUMOR CELLS EXHIBIT STAINING).

MGMT - POSITIVE (30% OF TUMOR CELLS)

EGFR wt - POSITIVE (2+ IN 90% OF TUMOR CELLS)

EGFR vIII - POSITIVE (2+ IN 20% OF TUMOR CELLS)

PTEN - LOSS (2+ IN 50% OF TUMOR CELLS)

S6 - NEGATIVE (2+ IN 20% OF TUMOR CELLS)

AKT - NEGATIVE (2+ IN 10% OF TUMOR CELLS)

MAPK - POSITIVE (3+ IN 20% OF TUMOR CELLS)

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]
Electronically signed: [REDACTED]

Performed by: [REDACTED]

Ordering MD: [REDACTED]

Consulting MDs: [REDACTED]

Source: NCI Genomic Data Commons file 87ed2043-a13c-426c-9626-bab1e6d678d2 (TCGA-12-3648.83E094A1-FC5F-4B3B-9F57-827A095BBA68.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).